Somatic mutation profile of tumor specimen TCGA-TM-A84H-01A (aliquot TCGA-TM-A84H-01A-11D-A36O-08) from TCGA case TCGA-TM-A84H, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Mixed glioma; Tissue or organ of origin: Cerebrum; Tumor grade: G3; Age at diagnosis: 44.6 years (16,277 days).
Specimen TCGA-TM-A84H-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5c5a61e4-b272-40c7-9a24-6bcc31b9cabf.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-TM-A84H-10A (Blood Derived Normal), aliquot TCGA-TM-A84H-10A-01D-A367-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0bc694b7-32d6-4bd9-967e-e3b49bcd60d9

The open-access MAF lists 41 somatic variants for this specimen: 37 protein-altering or splice-affecting, 4 silent.
By variant classification: Missense Mutation 31, Frame Shift Del 4, Silent 4, Splice Region 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- IDH1 | c.395G>A p.R132H | Missense Mutation (SNP) | VAF 28/80 reads (35%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.01); PolyPhen benign (0.047); catalogued as rs121913500, CM1310533, COSV61615239, COSV61615420; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- ARMCX5-GPRASP2 | c.835C>T p.P279S | Missense Mutation (SNP) | VAF 54/123 reads (44%) | SIFT tolerated (0.13); PolyPhen benign (0.003); catalogued as COSV100771990; called by muse, mutect2, varscan2
- CDH23 | c.8504T>C p.V2835A | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT tolerated (0.48); PolyPhen benign (0.006); catalogued as COSV99823652; called by muse, mutect2, varscan2
- CFAP65 | c.1164A>G p.V388= | Splice Region (SNP) | VAF 27/94 reads (29%) | catalogued as COSV99838445; called by muse, mutect2, varscan2
- CIDEC | c.460G>C p.D154H | Missense Mutation (SNP) | VAF 35/90 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100396745; called by muse, mutect2, varscan2
- CMYA5 | c.10016C>T p.A3339V | Missense Mutation (SNP) | VAF 21/52 reads (40%) | SIFT deleterious (0.03); PolyPhen benign (0.349); catalogued as rs932864869, COSV101484352; called by muse, mutect2, varscan2
- CSMD3 | c.1174G>A p.E392K | Missense Mutation (SNP) | VAF 141/211 reads (67%) | SIFT tolerated (0.61); PolyPhen probably damaging (0.935); catalogued as rs557572936, COSV52252824; called by muse, mutect2, varscan2
- CUL2 | c.1076A>C p.N359T | Missense Mutation (SNP) | VAF 28/113 reads (25%) | SIFT tolerated (0.31); PolyPhen benign (0.326); catalogued as COSV101039295; called by muse, mutect2, varscan2
- DCAF12L2 | c.92C>T p.A31V | Missense Mutation (SNP) | VAF 15/39 reads (38%) | SIFT tolerated (0.23); PolyPhen benign (0.144); catalogued as rs1261536454, COSV63580615, COSV63584127; called by muse, mutect2, varscan2
- DCANP1 | c.373C>T p.R125W | Missense Mutation (SNP) | VAF 60/160 reads (38%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0); catalogued as rs560339780, COSV101538277; called by muse, mutect2, varscan2
- DNAH17 | c.8692C>T p.R2898* | Nonsense Mutation (SNP) | VAF 17/90 reads (19%) | catalogued as rs762997608, COSV101103401; called by muse, mutect2, varscan2
- DNAI3 | c.1032G>C p.W344C | Missense Mutation (SNP) | VAF 9/55 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99642387; called by muse, mutect2, varscan2
- DSG2 | c.2878A>T p.S960C | Missense Mutation (SNP) | VAF 19/52 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.436); catalogued as COSV99853537; called by muse, mutect2, varscan2
- F8 | c.4674C>G p.N1558K | Missense Mutation (SNP) | VAF 39/197 reads (20%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as COSV100811911; called by muse, mutect2, varscan2
- FMO4 | c.826G>A p.G276R | Missense Mutation (SNP) | VAF 21/42 reads (50%) | SIFT tolerated (0.62); PolyPhen benign (0.01); catalogued as COSV100882167; called by muse, mutect2, varscan2
- FZD10 | c.1678G>A p.A560T | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT tolerated, low confidence (0.37); PolyPhen benign (0); catalogued as rs752575918, COSV99969586; called by muse, mutect2, varscan2
- GAS6 | c.1255C>G p.L419V | Missense Mutation (SNP) | VAF 22/73 reads (30%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.995); catalogued as rs149411733; called by muse, mutect2, varscan2
- GCNA | c.1393A>G p.T465A | Missense Mutation (SNP) | VAF 8/21 reads (38%) | SIFT deleterious (0.03); PolyPhen benign (0.019); catalogued as COSV101032694; called by muse, mutect2, varscan2
- GUCY1A1 | c.766T>C p.S256P | Missense Mutation (SNP) | VAF 5/82 reads (6%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.759); catalogued as COSV99638630; called by muse, mutect2
- IKBKE | c.1341G>A p.M447I | Missense Mutation (SNP) | VAF 9/23 reads (39%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100898380; called by muse, mutect2, varscan2
- MUC16 | c.14089G>C p.D4697H | Missense Mutation (SNP) | VAF 7/138 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.746); catalogued as COSV101201515, COSV67475881; called by muse, mutect2
- NFATC2 | c.117G>C p.L39F | Missense Mutation (SNP) | VAF 15/61 reads (25%) | SIFT tolerated (0.16); PolyPhen benign (0.026); catalogued as COSV101043667, COSV101044667; called by muse, mutect2, varscan2
- NGEF | c.1173C>G p.I391M | Missense Mutation (SNP) | VAF 21/44 reads (48%) | SIFT tolerated (0.27); PolyPhen benign (0.145); catalogued as COSV99890707; called by muse, mutect2, varscan2
- OTUB2 | c.68C>T p.P23L | Missense Mutation (SNP) | VAF 42/81 reads (52%) | SIFT tolerated (0.22); PolyPhen benign (0.116); catalogued as rs1316208630, COSV99180220; called by muse, mutect2, varscan2
- PCMTD2 | c.551del p.G184Efs*12 | Frame Shift Del (DEL) | VAF 14/111 reads (13%) | catalogued as rs1190339510; called by pindel, varscan2
- PLEKHA6 | c.925G>A p.A309T | Missense Mutation (SNP) | VAF 39/105 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); catalogued as COSV55334258; called by muse, mutect2, varscan2
- RAI1 | c.1766C>T p.A589V | Missense Mutation (SNP) | VAF 20/83 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.078); catalogued as rs1226126106, COSV99884967; called by muse, mutect2, varscan2
- SELE | c.974T>C p.F325S | Missense Mutation (SNP) | VAF 7/39 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs1385378143, COSV100325130; called by mutect2, varscan2
- SMARCA4 | c.3236C>T p.S1079L | Missense Mutation (SNP) | VAF 63/126 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.914); catalogued as COSV60789935; called by muse, mutect2, varscan2
- TP53 | c.512del p.E171Gfs*3 | Frame Shift Del (DEL) | VAF 71/103 reads (69%) | catalogued as CD098501, COSV52700191, COSV52740895, COSV53706637; called by mutect2, pindel, varscan2
- VRTN | c.1019C>T p.P340L | Missense Mutation (SNP) | VAF 33/73 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1175716420, COSV99832283; called by muse, mutect2, varscan2
- WNK1 | c.3559A>G p.K1187E (on ENST00000315939 / NM_018979.4; = p.K940E on NM_014823.3) | Missense Mutation (SNP) | VAF 4/80 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.628); catalogued as COSV100268555; called by muse, mutect2
- ZFYVE1 | c.949A>G p.I317V | Missense Mutation (SNP) | VAF 14/38 reads (37%) | SIFT tolerated (0.41); PolyPhen benign (0.2); catalogued as rs1489854016, COSV100607106; called by muse, mutect2, varscan2
- ZNF175 | c.1871T>C p.F624S | Missense Mutation (SNP) | VAF 27/117 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.886); catalogued as COSV99219753; called by muse, mutect2, varscan2
- ZNF99 | c.1298C>A p.A433D | Missense Mutation (SNP) | VAF 32/70 reads (46%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.843); catalogued as COSV68054948, COSV68054977; called by muse, mutect2, varscan2
- MACC1 | c.1349_1353del p.G450Efs*5 | Frame Shift Del (DEL) | VAF 33/59 reads (56%) | called by mutect2, pindel, varscan2
- MYT1 | c.618_621del p.S207Rfs*48 | Frame Shift Del (DEL) | VAF 10/80 reads (13%) | called by mutect2, pindel, varscan2
- DMD | c.3891C>T p.G1297= | Silent (SNP) | VAF 32/47 reads (68%) | catalogued as rs758317261, COSV63747600; called by muse, mutect2, varscan2
- OR52E4 | c.843T>C p.Y281= | Silent (SNP) | VAF 72/169 reads (43%) | catalogued as COSV100389369; called by muse, mutect2, varscan2
- VPS41 | c.1320A>G p.G440= | Silent (SNP) | VAF 10/71 reads (14%) | catalogued as COSV59649522; called by muse, mutect2, varscan2
- ZFX | c.519C>T p.T173= | Silent (SNP) | VAF 7/107 reads (7%) | catalogued as rs1205990234, COSV100458250, COSV58448464; called by muse, mutect2
